Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7243, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7243-01A (Primary Tumor).

[page 1 of 3]
Collected: [REDACTED]

Received: [REDACTED]

cc:

Case type: Surgical Case

Physician: [REDACTED]

Accession: [REDACTED]

DIAGNOSIS

(A) RIGHT PARTIAL GLOSSECTOMY:

INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features:

Gross: Ulcerating

Size: 2.2 cm in largest dimension

Invasion: Present, depth 1.0 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: Absent

Vascular Invasion: Absent

Lymphocyte Infiltration: Mild

Mucosal Margin: (radial) Negative for invasive carcinoma

Deep Margin: (radial) Close < 2mm

Dysplasia at Margin: Absent

(B) RIGHT EXTERNAL JUGULAR LYMPH NODE:

Lymph node, no tumor present

(C) ADDITIONAL ANTERIOR DEEP MARGIN #1 (TONGUE):

Skeletal muscle and nerve, no tumor present

(D) ADDITIONAL ANTERIOR DEEP MARGIN #2 (TONGUE):

Skeletal muscle, no tumor present

(E) RIGHT NECK DISSECTION, LEVEL 1:

Lymph nodes, no tumor present (0/2), Salivary gland, no tumor present

(F) RIGHT NECK DISSECTION, LEVEL 2A:

Lymph nodes, no tumor present (0/7)

(G) RIGHT NECK DISSECTION, LEVEL 2B:

Lymph nodes, no tumor present (0/5)

(H) RIGHT NECK DISSECTION, LEVEL 3:

METASTATIC SQUAMOUS CARCINOMA IN A LYMPH NODE (1/12)

Extranodal extension: Not present

(I) TOOTH:

Tooth, gross examination only

[page 2 of 3]
GROSS DESCRIPTION

(A) RIGHT PARTIAL GLOSSECTOMY – Received is a portion of right lateral tongue and associated floor of mouth (4.2 x 4.0 x 1.8 cm). The specimen contains a pale yellow, variegated, irregular mass which measures 2.5 x 2.0 x 1.0 cm. The mass is 0.8 cm from the anterior margin, 0.5 cm from the lateral margin and 1.0 cm from other margins. Frozen sections are performed in four cassettes, A1-A10, to assess margins. The remainder of the specimen is submitted from anterior to posterior in cassettes A11 through A15. [REDACTED]

*FS/DX: MUCOSAL MARGIN NEGATIVE, CLOSE DEEP (LATERAL), 1.0 MM. [REDACTED]

(B) RIGHT EXTERNAL JUGULAR LYMPH NODE – One lymph node 0.4 x 0.4 x 0.2 cm entirely submitted in B. [REDACTED]

(C) ADDITIONAL ANTERIOR DEEP MARGIN #1 (TONGUE) – Received for frozen section analysis is a 1.1 x 1.0 x 0.4 cm unoriented red-tan tissue which is submitted in toto in C. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(D) ADDITIONAL ANTERIOR DEEP MARGIN #2 (TONGUE) – Received for frozen section analysis is a 0.6 x 0.5 x 0.3 cm unoriented red-tan soft tissue fragment which is submitted in toto in D. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(E) RIGHT NECK DISSECTION, LEVEL 1 – The specimen consists of a salivary gland 4.5 x 2.8 x 1.5 cm and fibroadipose tissue 3.5 x 2.0 x 1.0 cm. The specimen is serially sectioned. Cut surface reveal unremarkable salivary glands. Two lymph nodes (0.3 x 0.2 x 0.2 and 0.6 x 0.4 x 0.3 cm) are identified in the fibrous adipose tissue.

SECTION CODE: E1, representative section of salivary gland; E2, two possible lymph nodes. [REDACTED]

(F) RIGHT NECK DISSECTION, LEVEL 2A – Fibroadipose tissue 3.0 x 2.5 x 1.2 cm. Seven lymph nodes are identified ranging from 0.2 x 0.2 x 0.2 to 2.0 x 0.7 x 0.6 cm.

SECTION CODE: F1, one lymph node; F2, three lymph nodes; F3, two lymph nodes; F4, one lymph node serially sectioned. [REDACTED]

(G) RIGHT NECK DISSECTION, LEVEL 2B – Fibroadipose tissue 2.2 x 2.0 x 0.8 cm. Five lymph nodes are identified ranging from 0.3 x 0.2 x 0.2 cm to 0.5 x 0.3 x 0.3 cm. Entirely submitted in G. [REDACTED]

(H) RIGHT NECK DISSECTION, LEVEL 3 – Fibroadipose tissue 4.0 x 2.5 x 1.0 cm. Multiple lymph nodes are identified ranging from 0.3 x 0.3 x 0.2 to 1.8 x 0.9 x 0.7 cm.

SECTION CODE: H1, four lymph nodes; H2, four lymph nodes; H3, three lymph nodes; H4, one lymph node serially sectioned. [REDACTED]

(I) TOOTH – A fragmented tooth (1.0 x 0.6 x 0.5 cm). The specimen is for gross examination only. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-53000, M-80703, M-43000, T-C4200, M-80706

[page 3 of 3]
Entire report and diagnosis completed by:

Source: NCI Genomic Data Commons file 0fe60820-6b98-44ed-a6be-7e0e03f717be (TCGA-CV-7243.59281142-CDC3-4028-9453-607A91578DDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).